Gene-level copy-number profile of tumor specimen C3L-06028-05 from CPTAC case C3L-06028, project CPTAC-3 (Skin — Nevi and Melanomas). Sex at birth: male; Vital status: Dead; Primary diagnosis: Malignant melanoma, NOS; Tissue or organ of origin: Skin, NOS; AJCC pathologic stage: Stage IIIB; Age at diagnosis: 59.4 years (21,694 days).
Specimen C3L-06028-05: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Metastatic; Specimen type: Solid Tissue; Biospecimen anatomic site: Skin; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file b7814848-72a4-4fa6-aa3c-445c36edbaf6.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator C3L-06028-31 (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 1,709 have no estimate.
https://portal.gdc.cancer.gov/files/4a03e1e0-b458-42f6-a4ac-8807af96146a

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 500; copy number 1: 2,403; copy number 2: 47,545; copy number 3: 3,462; copy number 4: 2,223; copy number 5: 2,105; copy number 6: 514; copy number 7: 3; copy number 8: 84; copy number 10: 75.

Homozygous deletions (total copy number 0; autosomes only): 1 gene in 1 contiguous region (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr11:95,768,953–95,790,409, 1 gene (within-gene range 0–2): FAM76B.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 2,781 genes in 9 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr5:151,742,316–151,772,532, 3 genes, copy number 5 (within-gene range 3–5): ATOX1, AC091982.1, RPLP1P6.
- chr7:46,476,457–48,647,497, 22 genes, copy number 6: AC004869.2, AC004869.1, HMGN1P19, AC011294.1, EPS15P1, AC004870.4, AC004870.2, AC004870.3, MRPL42P4, AC004870.1, TNS3, LINC01447, C7orf65, PKD1L1, LINC00525, C7orf69, AC069282.1, HUS1, SUN3, C7orf57, UPP1, ABCA13.
- chr7:62,275,361–62,275,678, 1 gene, copy number 5: AC128676.1.
- chr7:130,266,863–159,233,377, 651 genes, copy number 6–10 (broad region; genes not listed).
- chr14:18,333,726–18,412,264, 3 genes, copy number 7: CR383658.1, RNU6-458P, CR383658.2.
- chr15:19,878,555–19,973,218, 7 genes, copy number 5: AC138701.1, RNU6-978P, AC138701.2, AC127381.2, IGHV1OR15-9, SLC20A1P3, IGHV1OR15-2.
- chr15:22,125,511–101,820,197, 2,063 genes, copy number 5 (within-gene range 4–5) (broad region; genes not listed).
- chr20:63,627,227–63,936,031, 26 genes, copy number 5: MHENCR, STMN3, RTEL1, RTEL1-TNFRSF6B, TNFRSF6B, ARFRP1, ZGPAT, AL121845.3, AL121845.4, LIME1, AL121845.2, SLC2A4RG, ZBTB46, AL121845.1, ZBTB46-AS1, C20orf181, AL118506.1, ABHD16B, TPD52L2, DNAJC5, RNU1-134P, MIR941-1, MIR941-2, MIR941-3, MIR941-4, MIR941-5.
- chr21:12,999,676–13,120,807, 5 genes, copy number 5: AP001464.1, ANKRD30BP2, RNU6-614P, ZNF355P, AJ239321.1.

Autosomal genes at a single copy (total copy number 1): 46. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
